Gene-level copy-number profile of tumor specimen TARGET-20-PANTWV-04A from TARGET case TARGET-20-PANTWV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,230 days).
Specimen TARGET-20-PANTWV-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.c1480aba-b46d-5136-9583-7a3e7faa1ba8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PANTWV-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/97bacaf1-75c4-4e65-90c5-bef3cf54c283

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 454; copy number 2: 59,282; copy number 3: 1; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:144,364,364–144,579,434, 9 genes (within-gene range 0–2): ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412.
- chr5:88,717,117–88,904,257, 1 gene (within-gene range 0–2): MEF2C.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:29,824,742–29,826,711, 1 gene, copy number 5: ME2P1.
- chr12:32,000,375–32,007,435, 2 genes, copy number 5: AC016957.2, AC016957.1.
- chr19:33,283,978–33,285,739, 1 gene, copy number 5: AC008738.6.

Autosomal genes at a single copy (total copy number 1): 437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
